Somatic mutation profile of tumor specimen 0DG9JF from CCDI case PBBSXV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.8 years (5,046 days).
Specimen 0DG9JF: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3567c7c6-e957-4d4b-8135-97ffd0727cd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG9FR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/583a6ca8-8eb2-4e79-a2b8-3fe9c651fdbc

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 3, Frame Shift Del 2, Nonsense Mutation 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 138/418 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- NF1 | c.4998del p.P1667Lfs*31 (on ENST00000358273 / NM_001042492.3; = p.P1646Lfs*31 on NM_000267.3) | Frame Shift Del (DEL) | VAF 364/668 reads (54%) | catalogued as rs1135402867; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 176/462 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, varscan2
- BIRC6 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 140/394 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as COSV70200463; called by muse, varscan2
- MYOM2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 184/468 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs144235879; called by muse, varscan2
- NAAA | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 170/478 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as rs200736029; called by muse, varscan2
- SPIN2A | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1228287523; called by muse, varscan2
- ATM | c.5183_5184del p.K1728Sfs*20 | Frame Shift Del (DEL) | VAF 148/450 reads (33%) | called by pindel, varscan2
- CCDC18 | c.3880A>T p.K1294* (on ENST00000343253 / NM_001306076.1; = p.K1295* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 44/456 reads (10%) | called by muse, varscan2
- ITGB6 | c.622T>C p.F208L | Missense Mutation (SNP) | VAF 208/488 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TEK | c.2266G>A p.G756R | Missense Mutation (SNP) | VAF 199/516 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- CNOT3 | c.484-9C>T | Intron (SNP) | VAF 72/100 reads (72%) | catalogued as rs1042601186, COSV55359773; called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 14/118 reads (12%) | catalogued as COSV99987084; called by muse, varscan2
- GTF2A1L | chr2:48617833 G>A | 5'Flank (SNP) | VAF 80/215 reads (37%) | called by muse, varscan2
- MAML1 | c.1972-32G>C | Intron (SNP) | VAF 59/144 reads (41%) | called by muse, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 15/74 reads (20%) | catalogued as rs1012935800, COSV58726711; called by muse, varscan2
